Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GU-01A (Primary Tumor).

[page 1 of 3]
GROSS:

Specimen state: Fresh

Operation: Distal gastrectomy

Measurement: Greater curvature 17.0 cm

Lesser curvature 13.0 cm

Proximal resection margin 21.0 cm

Distal resection margin 7.5 cm

Duodenum 1.0 cm

Lesion: Ulcerofungating mass

Tumor size: 8.0 x 7.0 cm

Location: Antrum

Tumor type: AGC (Borrmann type III)

From proximal resection margin - 8.0 cm

From distal resection margin - 1.0 cm

Gross serosal invasion: No

100-0-3

adenocarcinoma, diffuse type 8145/3

Site: Stomach, antrum C16.3

hw 9/27/12

Blocks

T1-4 and TB, tumor and surrounding tissue x 5

A, antrum mucosa x 1

B and NB, body mucosa x 2

P, proximal resection margin x 1

D, distal resection margin of resected specimen x 1

LN1-2, superior gastric lymph nodes x 2

LN3-5, inferior gastric lymph nodes x 3

LN6, '1' lymph nodes x 1

LN7, '4sb' lymph nodes x 1

LN8, '5' lymph nodes x 1

LN9-10, '6' lymph nodes x 2

LN11, '7' lymph nodes x 1

LN12-13, '8' lymph nodes x 2

LN14, '9' lymph nodes x 1

LN15-16, '11p' lymph nodes x 2

LN17 '12' lymph nodes x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma

Differentiation: Poorly differentiated

(solid component: 50%, mucin productin: 40%, glandular component 10%)

[page 2 of 3]
Depth of tumor invasion:

T3: Tumor penetrates subserosal connective tissue without invasion of visceral peritoneum or adjacent structures

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Diffuse

Ming classification (Growth pattern): Expanding

Lymphoid reaction: Present

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastasis: Present (2/56)

Pathologic stage: pT3N1Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, distal gastrectomy:

Adenocarcinoma, poorly differentiated, infiltrating
(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type *per clarification by TSS.*

Lymph node, perigastric, distal gastrectomy:

Superior gastric: No tumor present (0/10)

Inferior gastric: No tumor present (0/10)

Lymph node, regional, biopsy:

Labeled as '1': No tumor present (0/4)

Labeled as '4sb': No tumor present (0/5)

Labeled as '5': Metastatic carcinoma, primary in stomach (2/2)

Labeled as '6': No tumor present (0/8)

Labeled as '7': No tumor present (0/3)

Labeled as '8': No tumor present (0/3)

Labeled as '9': No tumor present (0/3)

Labeled as '11p': No tumor present (0/9)

Labeled as '12': No tumor present (0/1)

Reviewed Initials:	9/7/12	

9/29/12

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Adenocarcinoma Poorly Differentiated (solid component 50%, mucin productin 40%, glandular component 10%) , Diffuse	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Original pathology report (for the whole resected specimen) mentioned 40% of mucin productin, which was not found in TCGA top slide. Review of top slide confirmed that this tumor is a stomach adenocarcinoma-diffuse type (originally described as Stomach Adenocarcinoma Poorly Differentiated (solid component 50%, mucin productin 40%, glandular component 10%) , Diffuse)	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bdf969f6-a29e-4808-adaf-8f12ef149a40 (TCGA-HU-A4GU.E576F53B-29FF-48F6-BDA8-55C85A186B9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).